Somatic mutation profile of tumor specimen TARGET-30-PARUPN-01A (aliquot TARGET-30-PARUPN-01A-01D) from TARGET case TARGET-30-PARUPN, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 10.0 years (3,636 days).
Specimen TARGET-30-PARUPN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56a5d47d-80ac-4d94-a2c7-1d80bc57dfdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARUPN-10A (Blood Derived Normal), aliquot TARGET-30-PARUPN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dd5a1fb-718d-4862-834b-1ac27972d254

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GIMAP7 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV57958618; called by muse, mutect2, varscan2
- ADAM30 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 28/755 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CEACAM3 | c.361A>C p.T121P | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH17 | c.9665G>A p.G3222D | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.139); called by muse, mutect2
- ZNF827 | c.2937C>T p.N979= | Silent (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
